Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7607, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7607-01A (Primary Tumor).

Microscopic

Permanent section of the frozen section specimen demonstrates mildly hypercellular gray and white matter, Here the hypercellularity is more evident than on the frozen section slides. Some atypical in also seen. Whereas some reactive astrocytes are present, the biopsy is convincing for infiltrating glioma

Sections again demonstrate gray and white matter that is diffusely infiltrated by a mildly hypercellular glial neoplasm, the tumor cells tend to be round to oval nuclei with only a few asphasic.... However, .. perinuclear halos or other classic glioma features are not seen. No mitotic figures are seen.

Addendum

Scattered MIB-1 reactive cells present with a calculated labeling index of 1.7%, indicative of modestly proliferative neoplasm and consistent with the low grade histologic features.

Diagnosis

Consistent with well differentiated astrocytoma

Source: NCI Genomic Data Commons file fd1d4b29-1bc5-4fab-8762-85f003f3232e (TCGA-HT-7607.564D0FDC-517D-4CC7-817B-AF5F9280F4BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).